MMRF case MMRF_2041 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e09a0b20-e83c-46f1-89bc-305b570ad285

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.0 years (19,344 days); ISS stage: II; Days to last known disease status: 973 days (2.7 years); Days to last follow up: 973 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 29 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 108 days; Days to treatment end: 108 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 199 days; Days to treatment end: 497 days (1.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 497 days (1.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -39 (ECOG 0): M Protein 4.75 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 173 mg/dL; Immunoglobulin G 3.74 g/L; Immunoglobulin A 37.2 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 4.2 µg/mL; Hemoglobin 5.15 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.6 mmol/L; Albumin 34 g/L; Total Protein 10.1 g/dL; Glucose 7.65 mmol/L; C-Reactive Protein 0.1 mg/dL.
- Day 121 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.698 mg/dL; Immunoglobulin G 5.55 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 5.58 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.52 ×10⁹/L; Platelets 28 ×10⁹/L; Creatinine 42.4 µmol/L; Blood Urea Nitrogen 1.07 mmol/L; Calcium 1.83 mmol/L; Albumin 28 g/L; Total Protein 4.7 g/dL; Glucose 6 mmol/L.
- Day 217 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.285 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.688 mg/dL; Immunoglobulin G 6.69 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.28 mmol/L; Albumin 46 g/L; Total Protein 6.6 g/dL; Glucose 5.17 mmol/L.
- Day 308 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.843 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.59 mg/dL; Immunoglobulin G 9.67 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 1.4 µg/mL; Hemoglobin 8.12 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 104 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.15 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.56 mmol/L.
- Day 399 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.638 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.4 mmol/L; Albumin 47 g/L; Total Protein 7.5 g/dL; Glucose 5.39 mmol/L.
- Day 497 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.954 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 9.92 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 1.4 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.39 mmol/L.
- Day 588 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 9.88 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 3.91 mmol/L.
- Day 672 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 87 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 7.2 g/dL; Glucose 5.39 mmol/L.
- Day 763 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.71 mg/dL; Immunoglobulin G 9.51 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 4.95 mmol/L.
- Day 854 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.64 mg/dL; Immunoglobulin G 9.86 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 4.73 mmol/L.
- Day 973 (ECOG 0): Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.23 mmol/L.

Other clinical attributes
- Day -39: Weight: 49 kg; Height: 156 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2041_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -39 days.
- Sample MMRF_2041_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -39 days.
